Gene-level copy-number profile of tumor specimen TCGA-FG-A6J3-01A from TCGA case TCGA-FG-A6J3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.4 years (19,138 days).
Specimen TCGA-FG-A6J3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.988c479a-5bf5-4797-a4b3-2340bdb81065.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FG-A6J3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/31f9ca11-9652-4b44-b62f-4dd64d2e30c1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 503; copy number 2: 3,837; copy number 3: 13,977; copy number 4: 35,762; copy number 5: 3,315; copy number 6: 795; copy number 7: 135; copy number 8: 574; copy number 9: 114; copy number 10: 83; copy number 11: 86; copy number 13: 336; copy number 17: 2; copy number 18: 54; copy number 20: 72; copy number 21: 50; copy number 22: 15; copy number 24: 48; copy number 28: 51; copy number 37: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FG-A6J3-01A-11D-A31K-01): tumor purity 0.68, ploidy 3.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:3,636,459–3,663,103, 1 gene (within-gene range 0–5): CTNS.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 912 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:171,058,414–171,460,408, 1 gene, copy number 11 (within-gene range 8–11): TNIK.
- chr3:171,439,526–178,937,352, 85 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr4:53,265,461–65,698,029, 157 genes, copy number 10–20 (broad region; genes not listed).
- chr12:2,603,350–11,895,377, 390 genes, copy number 13–18 (broad region; genes not listed).
- chr12:38,078,529–44,921,848, 91 genes, copy number 24–37 (within-gene range 2–37) (broad region; genes not listed).
- chr12:50,923,472–51,173,135, 16 genes, copy number 9 (within-gene range 2–9): METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P.
- chr12:55,870,048–58,395,138, 147 genes, copy number 9–21 (broad region; genes not listed).
- chr12:61,600,067–61,702,771, 2 genes, copy number 24: DUX4L52, AC090629.1.
- chr12:62,021,570–62,022,174, 1 gene, copy number 21: RPS3P6.
- chr12:71,439,798–71,927,248, 15 genes, copy number 22 (within-gene range 2–22): LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:73,820,315–74,402,600, 7 genes, copy number 24 (within-gene range 2–24): LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3.

Autosomal genes at a single copy (total copy number 1): 502. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
